FM case AD15532 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Gallbladder.
https://portal.gdc.cancer.gov/cases/909ad6ba-6dca-4185-9407-3a478efaaa76

Female, 39.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the gallbladder; primary biopsied or resected from the gallbladder. Tumor nuclei on the sequenced sample's slide: 33% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
